MMRF case MMRF_2013 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/79b9b609-45a2-4781-a652-53a13843082c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 61.5 years (22,453 days); ISS stage: I; Days to last known disease status: 996 days (2.7 years); Days to last follow up: 996 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 165 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 224 days; Days to treatment end: 225 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 227 days; Days to treatment end: 227 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 0): M Protein 2.74 g/dL; Immunoglobulin G 35.5 g/L; Immunoglobulin A 0.49 g/L; Immunoglobulin M 0.53 g/L; Beta 2 Microglobulin 2.8 µg/mL; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 6.77 ×10⁹/L; Absolute Neutrophil 4.61 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 69.8 µmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 8.4 g/dL; Glucose 5.45 mmol/L; C-Reactive Protein 0.89 mg/dL.
- Day 85: M Protein 0.32 g/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 0.72 g/L; Immunoglobulin M 0.51 g/L; Beta 2 Microglobulin 2.23 µg/mL; Lactate Dehydrogenase 5.95 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 5.54 ×10⁹/L; Absolute Neutrophil 3.44 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 65.4 µmol/L; Calcium 2.2 mmol/L; Glucose 6.71 mmol/L.
- Day 183 (ECOG 0): M Protein 0.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 19.8 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 0.94 g/L; Immunoglobulin M 0.43 g/L; Beta 2 Microglobulin 2.1 µg/mL; Lactate Dehydrogenase 4.13 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 5.22 ×10⁹/L; Absolute Neutrophil 3.36 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL.
- Day 260: M Protein 0 g/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 0.81 g/L; Immunoglobulin M 0.5 g/L; Beta 2 Microglobulin 2 µg/mL; Hemoglobin 6.82 mmol/L; Leukocytes 4.79 ×10⁹/L; Absolute Neutrophil 2.02 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.28 mmol/L; Albumin 38.1 g/L; Total Protein 6.5 g/dL; Glucose 6.11 mmol/L.
- Day 351: M Protein 0.07 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 17.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 83.9 mg/dL; Immunoglobulin G 12.6 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 1.45 g/L; Beta 2 Microglobulin 2.35 µg/mL; Hemoglobin 7.56 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.47 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.2 mmol/L; Total Protein 6.1 g/dL; Glucose 4.73 mmol/L.
- Day 435: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.25 mg/dL; Immunoglobulin G 13.9 g/L; Immunoglobulin A 0.96 g/L; Immunoglobulin M 0.66 g/L; Beta 2 Microglobulin 1.93 µg/mL; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 8.99 ×10⁹/L; Absolute Neutrophil 5.64 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.2 mmol/L; Albumin 39.9 g/L; Total Protein 6.9 g/dL.
- Day 526: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 19.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 29.8 mg/dL; Immunoglobulin G 12.7 g/L; Immunoglobulin A 1.29 g/L; Immunoglobulin M 1.71 g/L; Beta 2 Microglobulin 1.7 µg/mL; Hemoglobin 8.68 mmol/L; Leukocytes 6.54 ×10⁹/L; Absolute Neutrophil 3.97 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 4.17 mmol/L; Calcium 2.13 mmol/L; Glucose 4.9 mmol/L.
- Day 625 (ECOG 1): Immunoglobulin G 9.81 g/L; Immunoglobulin A 1.05 g/L; Immunoglobulin M 0.52 g/L; Beta 2 Microglobulin 1.41 µg/mL; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.83 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 3.5 mmol/L; Calcium 2.15 mmol/L; Albumin 38.1 g/L; Total Protein 6.1 g/dL; Glucose 4.9 mmol/L.
- Day 716 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 1.22 g/L; Immunoglobulin M 0.72 g/L; Beta 2 Microglobulin 1.63 µg/mL; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 3.53 ×10⁹/L; Absolute Neutrophil 2.15 ×10⁹/L; Platelets 102 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 12.3 mmol/L; Calcium 2.2 mmol/L; Albumin 35.9 g/L; Total Protein 6 g/dL; Glucose 7.76 mmol/L.
- Day 821 (ECOG 0): M Protein 0 g/dL; Immunoglobulin G 4.76 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 1.78 µg/mL; Lactate Dehydrogenase 3.35 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.13 ×10⁹/L; Absolute Neutrophil 2.46 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 6 mmol/L; Calcium 2.25 mmol/L; Albumin 40.7 g/L; Total Protein 5.9 g/dL; Glucose 5.12 mmol/L.
- Day 996 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 6.91 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 1.6 µg/mL; Hemoglobin 8.8 mmol/L; Leukocytes 7.48 ×10⁹/L; Absolute Neutrophil 5.45 ×10⁹/L; Platelets 100 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 7.83 mmol/L; Calcium 2.1 mmol/L; Albumin 36.4 g/L; Total Protein 6.3 g/dL; Glucose 5.01 mmol/L.

Other clinical attributes
- Day -6: Weight: 62 kg; Height: 164 cm.

Biospecimens (2 samples)
- Sample MMRF_2013_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_2013_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
